Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A01Z, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A01Z-01A (Primary Tumor).

TCGA #:

Sample ID #

This tumor is a poorly differentiated invasive adenocarcinoma (in this case, ascending carcinoma, G 3), with infiltration of the fatty connective tissue and lymph vessel invasions, L 1. The resection margins are free resection margins, orally of the ileum type, distally of the colon type with corresponding three layers of mucosa, submucosa and muscularis.

The ligature consists of fatty connective tissue with vascular components.

The lymph nodes are free lymph nodes, pN0 (0 of 12).

Tumor classification:

ICDO-DA-M 8140/3

G 3

pT3, pN0, MX, L1

ICD-O 3

adenocarcinoma, NOS 8140/3

Site: ascending colon C18.2 w 3/30/11

Criteria	Yes
ICDPA Discrepancy	☒

Source: NCI Genomic Data Commons file df42ca1b-e65a-4913-a1f6-e51346f0bf9e (TCGA-AA-A01Z.E8C798B9-30E0-40B0-93B3-49ABD6E7F29A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).